Somatic mutation profile of tumor specimen TCGA-UZ-A9PP-01A (aliquot TCGA-UZ-A9PP-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9PP, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdfa22d2-d176-4f79-bf9f-4f7bd20007ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PP-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PP-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c35de3be-af92-44dd-bf50-c03e6b68befb

The open-access MAF lists 78 somatic variants for this specimen: 64 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 11, Nonsense Mutation 4, Frame Shift Ins 2, 3'UTR 1, Splice Site 1, 5'UTR 1, Intron 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRB3 | c.2348T>A p.I783N | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV100999660; called by muse, mutect2, varscan2
- AOPEP | c.2114A>G p.K705R (on ENST00000375315 / NM_001193329.1; = p.K606R on NM_032823.5) | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as COSV99948624; called by muse, mutect2, varscan2
- APOC4 | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99376895; called by muse, mutect2, varscan2
- ATP1A3 | c.1612A>T p.K538* (on ENST00000545399 / NM_001256214.2; = p.K525* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100131927; called by muse, mutect2, varscan2
- ATP5MC3 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99507044; called by muse, mutect2, varscan2
- BCAR3 | c.1058C>G p.S353W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV99550201; called by muse, mutect2, varscan2
- BCOR | c.3043T>C p.Y1015H | Missense Mutation (SNP) | VAF 117/138 reads (85%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.671); catalogued as COSV100652836; called by muse, mutect2, varscan2
- BPTF | c.8194C>T p.Q2732* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100073976; called by muse, mutect2, varscan2
- CDK12 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV101420357, COSV70999607, COSV71002685; called by muse, mutect2, varscan2
- CHMP3 | c.69A>G p.I23M | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as rs540948421, COSV99806498; called by muse, mutect2, varscan2
- CMAS | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99982533; called by muse, mutect2, varscan2
- COL18A1 | c.2122G>A p.D708N (on ENST00000359759 / NM_130444.3; = p.D473N on NM_030582.4) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV100700428; called by muse, mutect2, varscan2
- COL4A1 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs757882197, COSV101010954; called by muse, mutect2, varscan2
- COL4A1 | c.1525G>C p.A509P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101010955; called by muse, mutect2, varscan2
- CWC27 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV101126419; called by muse, mutect2
- DDHD1 | c.1501A>C p.M501L (on ENST00000323669; = p.M698L on NM_030637.3) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV100079008; called by muse, mutect2, varscan2
- FOXC1 | c.500T>C p.F167S | Missense Mutation (SNP) | VAF 78/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101083218; called by mutect2, varscan2
- GPBP1 | c.1161-1G>A p.X387_splice | Splice Site (SNP) | VAF 45/103 reads (44%) | catalogued as COSV99302369; called by muse, mutect2, varscan2
- HELZ2 | c.6403C>G p.P2135A (on ENST00000467148 / NM_001037335.2; = p.P1566A on NM_033405.3) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101427515; called by muse, mutect2, varscan2
- ICMT | c.788A>T p.Y263F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100658208; called by muse, mutect2, varscan2
- IL10RB | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99269758; called by muse, mutect2, varscan2
- IL9 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.176); catalogued as rs774133953, COSV50853707; called by muse, mutect2, varscan2
- INTS9 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101273797; called by muse, mutect2, varscan2
- INTS9 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 55/65 reads (85%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as rs1007083454, COSV101273798; called by muse, mutect2, varscan2
- ITGB8 | c.2186A>G p.K729R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV99750502; called by muse, mutect2, varscan2
- KATNAL2 | c.968T>G p.I323S (on ENST00000356157 / NM_001353899.1; = p.I251S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776952743, COSV99795851; called by muse, mutect2, varscan2
- KCNB2 | c.116T>G p.I39S | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101578646; called by muse, mutect2, varscan2
- KMT2E | c.2159T>G p.L720R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.183); catalogued as COSV99995746; called by muse, mutect2, varscan2
- KNTC1 | c.2949G>A p.M983I | Missense Mutation (SNP) | VAF 99/186 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1173558821, COSV100337902; called by muse, mutect2, varscan2
- LRRN2 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs535832685, COSV100912738; called by muse, mutect2, varscan2
- LTBP3 | c.944A>T p.K315M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100098868; called by muse, mutect2, varscan2
- MLLT1 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV99397847; called by muse, mutect2, varscan2
- MUC16 | c.23288C>G p.T7763R | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.887); catalogued as rs567112342, COSV101198054, COSV67463888; called by muse, mutect2, varscan2
- MYH14 | c.405C>T p.Y135= | Splice Region (SNP) | VAF 27/60 reads (45%) | catalogued as rs1356321548, COSV51833068, COSV99221656; called by muse, mutect2, varscan2
- NPC1 | c.3758C>A p.P1253Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99339832; called by muse, mutect2, varscan2
- OAT | c.397T>C p.Y133H | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100920355; called by muse, mutect2, varscan2
- OBSCN | c.14503G>A p.V4835I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99472165; called by muse, mutect2, varscan2
- OMG | c.661A>C p.T221P | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV99907798; called by muse, mutect2, varscan2
- OR10C1 | c.509G>A p.C170Y (on ENST00000622521; = p.C168Y on NM_013941.3) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762015707, COSV101010785; called by muse, mutect2, varscan2
- PHF20 | c.1165G>C p.G389R | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV100179858; called by muse, mutect2, varscan2
- POLR1A | c.1846C>T p.Q616* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99807069; called by muse, mutect2, varscan2
- PRR14 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99788258; called by muse, mutect2, varscan2
- RC3H1 | c.2428T>C p.Y810H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99281010; called by muse, mutect2, varscan2
- SAFB | c.2206T>C p.Y736H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV99412491; called by muse, mutect2, varscan2
- SCN9A | c.3711C>A p.F1237L (on ENST00000303354; = p.F1226L on NM_002977.3) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269325856, COSV100311260; called by muse, mutect2, varscan2
- SLC28A1 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV99722493; called by muse, mutect2
- SPTBN1 | c.4673T>G p.L1558R | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV100441736; called by muse, mutect2
- TPCN1 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs764138445, COSV52530928; called by muse, mutect2, varscan2
- TRMT2A | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99349750; called by muse, mutect2, varscan2
- TTN | c.3832A>T p.K1278* (on ENST00000591111; = p.K1232* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | catalogued as COSV100593228; called by muse, mutect2, varscan2
- ULK3 | c.44T>C p.I15T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV99173918; called by muse, mutect2
- URGCP | c.2021G>T p.W674L (on ENST00000453200 / NM_001077663.3; = p.W665L on NM_017920.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99786937; called by muse, mutect2, varscan2
- VMO1 | c.577A>G p.N193D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99564547; called by muse, mutect2, varscan2
- WASL | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99771474; called by muse, mutect2, varscan2
- ZBTB7B | c.817T>A p.Y273N (on ENST00000292176; = p.Y307N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV99420745; called by muse, mutect2, varscan2
- ZCCHC7 | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV100382707; called by muse, mutect2, varscan2
- ZNF589 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100685520; called by muse, mutect2, varscan2
- ZNF692 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV100133711; called by muse, mutect2
- ZSCAN1 | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV99991303; called by muse, mutect2, varscan2
- DAZAP1 | c.205_210del p.A69_S70del | In Frame Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- ESF1 | c.22dup p.M8Nfs*3 | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.3754dup p.H1252Pfs*2 | Frame Shift Ins (INS) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- SEMG2 | c.87del p.G30Afs*42 | Frame Shift Del (DEL) | VAF 76/164 reads (46%) | called by mutect2, pindel, varscan2
- ABCG4 | c.171A>T p.S57= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV100266500; called by muse, mutect2, varscan2
- AKAP8 | c.768C>T p.Y256= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs1343180881, COSV99511685; called by muse, mutect2, varscan2
- ALDH18A1 | c.1167C>A p.I389= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100973049; called by muse, mutect2
- ALPK2 | c.6378A>G p.K2126= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100864084; called by muse, mutect2, varscan2
- CALCA | c.75A>T p.A25= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100523896; called by muse, mutect2, varscan2
- KLHDC7A | c.912C>A p.G304= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV101272710; called by muse, mutect2, varscan2
- MDH2 | c.729A>G p.G243= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1369704251, COSV100242553; called by muse, mutect2, varscan2
- MERTK | c.360T>G p.P120= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV99774000; called by muse, mutect2, varscan2
- RBM27 | c.46T>C p.L16= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99505639; called by muse, mutect2, varscan2
- SLCO4A1 | c.1842C>A p.A614= | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as COSV53891740, COSV99414436; called by muse, mutect2, varscan2
- SPANXB1 | c.153T>C p.S51= | Silent (SNP) | VAF 153/492 reads (31%) | called by muse, mutect2, varscan2
- NPR3 | c.*3215T>C | 3'UTR (SNP) | VAF 59/135 reads (44%) | catalogued as COSV99422195; called by muse, mutect2, varscan2
- SQSTM1 | c.-2C>T | 5'UTR (SNP) | VAF 12/33 reads (36%) | catalogued as rs755172841, COSV100657618, COSV62435005; called by muse, mutect2, varscan2
- VPS39 | c.139+266A>T | Intron (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100528938; called by muse, mutect2, varscan2
